Somatic mutation profile of tumor specimen TARGET-30-PASBMW-01A (aliquot TARGET-30-PASBMW-01A-01D) from TARGET case TARGET-30-PASBMW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.5 years (1,646 days).
Specimen TARGET-30-PASBMW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a953ce0c-3c96-4c13-9b46-1040e776e501.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASBMW-10A (Blood Derived Normal), aliquot TARGET-30-PASBMW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73c78cb3-c5b3-49e2-a424-d86243400b1f

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- DNAH2 | c.3123G>T p.E1041D | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV66729566; called by muse, mutect2, varscan2
- PCLO | c.13027C>A p.P4343T | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61644383, COSV61679972; called by muse, mutect2, varscan2
- DOCK8 | c.5805C>A p.I1935= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV66624964; called by muse, mutect2, varscan2
